Surgical pathology report (de-identified scan), TCGA case TCGA-VN-A88K, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site NCI Urologic Oncology Branch, specimen TCGA-VN-A88K-01A (Primary Tumor).

[page 1 of 5]
Gender: Male	Birth Date:	Admit Date:
Attending:	Admit Protocol:	Age:
		Location:

Surgical Pathology	Final Results
--------------------	---------------

CASE NUMBER: DIAGNOSIS:	Final
----------------------------	-------

1. Lymph node, overlying aortic bifurcation, excision: Lymph node. No tumor seen (0/1).
2. Lymph node, right common iliac artery, excision: Metastatic prostatic adenocarcinoma to two lymph nodes (2/6). Extracapsular invasion is identified.
3. Lymph node, right external iliac artery, excision: Lymph nodes. No tumor seen (0/3).
4. Lymph node, internal iliac and obturator, right, excision: Metastatic prostatic adenocarcinoma to six lymph nodes (6/6). Extracapsular invasion is identified.
5. Lymph node, internal iliac vein, right, excision: Metastatic prostatic adenocarcinoma to two lymph nodes (3/8). Extracapsular invasion is identified.
6. Lymph node, external iliac artery, left, excision: Metastatic prostatic adenocarcinoma to two lymph nodes (2/6).
7. Lymph node, external iliac vein, left, excision: Fibroadipose tissue. No tumor seen.
8. Lymph node, obturator packet, left, excision: Metastatic prostatic adenocarcinoma to two lymph nodes (2/5).
9. Lymph node, common iliac vein, left, excision: Lymph node. No tumor seen (0/2).
10. Lymph node and fat, anterior prostate, excision: Fibroadipose tissue. No tumor seen.
11. Prostate, prostatectomy: Adenocarcinoma, poorly differentiated, Gleason's predominant score 8(4+4) with a small component of 9(4+5), involving the entire right lobe and 15% of the left lobe. Extracapsular invasion is present in the right lobe posteriorly and anteriorly. Perineural invasion is present. The seminal vesicle and inked margins are free of tumor.

G6CF ICD-O-3
Adenocarcinoma, acinar
path 8140/3
Adenocarcinoma NOS 8140/3
Site: Prostate NOS
061.9
JW 10/7/13

NOTE: The findings were discussed with
See table below.

Prostate Radical Prostatectomy Summary Table

Microscopic
Histologic Type: poorly differentiated adenocarcinoma.
Histologic Grade: Gleason's predominant score 8(4+4) with a small

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974.

Requested By:

Do not file in Medical Record

[page 2 of 5]
Gender: Male	Birth Date:	Admit Protocol:
Admit Protocol:	Admit Protocol:	Age:
		Location:

Surgical Pathology	Final Results
--------------------	---------------

compartment of 9(4+5)

Extent of Invasion

Primary Tumor(pT): pT3a
Regional Lymph Nodes(pN): pN1
Distant Metastasis(pM): pMX
Residual Tumor (R): RX
Margins: NEGATIVE
Extraprostatic Extension: PRESENT
Seminal Vesicle Invasion: ABSENT
Perineural Invasion: PRESENT
Lymphatic Invasion: PRESENT

Additional Pathologic Findings:

Immunoperoxidase and in-situ hybridization tests performed here and used for diagnosis were developed and their performance characteristics determined by ~~the laboratory~~ They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION: Allocate Order to Protocol Brief
Clinical History: prostate
cancer Specimen Taken For Protocol: 01 - Yes

PROCEDURE: Pre-Operative Diagnosis: prostate cancer Post-Operative
Diagnosis:
prostate cancer Operative Findings: c/w diagnosis

SPECIMENS SUBMITTED: 1. LYMPH NODES, Overline aortic bifurcation
2. LYMPH NODES, Right common iliac artery
3. LYMPH NODES, Right exyernal iliac artery
4. OBTURATOR LYMPH NODE(S), Right internal iliac artery iliac vein
5. LYMPH NODES, Right internal iliac vein
6. LYMPH NODES, Left external iliac artery
7. LYMPH NODES, Left external iliac vvein
8. OBTURATOR LYMPH NODE(S), Left packet
9. LYMPH NODES, Left common iliac vein
10. FAT, And lymph node over anterior
11. LYMPH NODES

GROSS DESCRIPTION: Received in 10 formalin-filled containers labeled with the patient's name, medical record number, and further specified as follows:

[page 3 of 5]
Gender: Male		Birth Dat	Admit Protocol:
Admit Protocol:		Admit Protoco	Age:
			Location

Surgical Pathology**Final Results**

1. "Lymph nodes overlying aortic bifurcation". The specimen consists of a yellow to tan fibroadipose tissue measuring 3 x 2 x 0.5 cm. The specimen is serially sectioned and submitted in cassettes 1A - C for permanent processing.
2. "Right common iliac artery lymph node". The specimen consists of 2 fibroadipose tissue fragments measuring 4 x 2 x 0.5 and 1.5 x 1 x 0.5 cm. Three candidate lymph nodes measuring from 0.3 to 1.2 cm in greatest dimension are identified.

Summary of cassettes submitted for permanent processing:

2A: Two candidate lymph nodes, bivalved.

2B: Two candidate lymph nodes.

2C: One candidate lymph node, bivalved.

2E - F: Remaining fibroadipose tissue.

3. "Right external iliac artery lymph node". The specimen consists of 3 fibroadipose soft tissue fragments measuring 1 x 1 x 0.5 and 1 x 3 x 0.5 and 2 x 1 x 0.8 cm. Two candidate lymph nodes measuring 0.5 and 1.2 cm in greatest dimension are identified. Lymph nodes are submitted in cassette 3A and the remaining fibroadipose tissue is submitted in cassettes 3B - C.

4. "Right internal iliac artery and vein and right obturator lymph node". The specimen consists of 2 tissue fragments measuring 3.5 x 1 x 0.7 and 4.5 x 2.5 x 0.5. A matted fragment presumed to be a candidate lymph node measuring 4 x 1 x 0.5 is identified. Additional firm nodular candidate lymph nodes measuring from 0.3 to 2 cm in greatest dimension are identified.

Summary of cassettes submitted for permanent processing:

4A - B: Largest candidate lymph node, bivalved.

4C: Smaller candidate lymph nodes.

4D: Four candidate lymph nodes are submitted.

4E: Additional candidate lymph nodes.

4F: Two matted areas, bivalved.

4G - H: Remaining fibroadipose tissue.

5. "Right internal iliac vein lymph node". The specimen consists of a yellow fibroadipose tissue fragment measuring 4 x 3 x 0.2 cm. A firm nodular area measuring 0.5 x 0.4 x 0.5 cm is identified. The nodule presumed lymph node is submitted bivalved in cassette 5A and the remaining fibroadipose tissue is submitted in cassettes 5B- H.

6. "Left external iliac artery LN". The specimen consists of a matted white to tan soft tissue fragment measuring 4.5 x 1 x 0.5 cm. Three distinct lymph nodes are identified, 1 measuring from 0.5 to 2.5 cm in greatest dimension. The larger of the lymph nodes is submitted in cassette 6A bivalved. Another lymph node is submitted in cassette 6B.

7. "Left external iliac vein lymph node". The specimen consists of a tan to yellow fibroadipose tissue fragment measuring 2 x 1.5 x

[page 4 of 5]
Gender: Male		Birth Date:	Admit Protocol:
Admit Protocol:		Admit Protocol	Age:
			Location:

Surgical Pathology	Final Results
--------------------	---------------

0.4 cm. The specimen is entirely submitted in cassette labeled A for permanent processing.

8. "Left obturator lymph node packet". The specimen consists of multiple nodular soft tissue fragments measuring 3 x 2.5 x 0.7 cm. Candidate lymph nodes are identified measuring from 0.5 to 2.0 cm in greatest dimension.

Summary of cassettes submitted for permanent processing:

8A: Largest lymph node, bivalved.

8B: Lymph node, bivalved.

8C: Two lymph nodes.

8D: Two lymph

8E: Remaining fibroadipose tissue.

9. "Left common iliac vein LN". The specimen consists of a single fibroadipose tissue fragment with 2 nodular areas. The specimen measures 2 x 2 x 0.3 cm and the nodular areas measure 0.7 and 1.0 cm in greatest dimension. The entire specimen is submitted in cassette labeled 9A for permanent processing.

10. "Fat and LN over anterior prostate". The specimen consists of yellow fibroadipose tissue measuring 4 x 2 x 0.3 cm. The specimen is bisected and submitted in entirety in cassettes 10A - B for permanent processing.

11. "Prostate" consists of a prostatectomy specimen weighing 87.5 grams with the following measurements: Left to right: 5.5 cm, anterior to posterior 4.5 cm, apex to base 5.5 cm, left seminal vesicle 5 x 2.5 x 1 cm, left vas deferens 5 x 0.5 cm, right seminal vesicle 3.5 x 2 x 2.2 cm, right vas deferens 6 x 0.5 cm. The prostate is inked as follows: Urethra in yellow, anterior one-third in black, right posterior two-thirds in blue, and left posterior two-thirds in red. Gross photographs are taken. One cut is made revealing a nodular cut surface and a large nodule on the right. Approximately 2 x 1 x 0.3 cm of tissue from the nodule and approximately 1 x 1 x 0.2 cm of the tissue from the left side of normal-appearing prostatic tissue are procured for the by The procurement was documented b n

Received in the a specimen matching the above description. The vas deferens and seminal vesicles are separated from the prostate gland and the prostate is serially sectioned with a fabricated mold. The vas deferens and seminal vesicles are serially sectioned. The right vas deferens is filled with a chocolate colored gelatinous material.

Summary of cassettes submitted for permanent processing:

11A - H: Serial sections of prostate.

11I - J: Right seminal vesicle and vas deferens where they remain attached.

11K - Q: Remaining right vas deferens.

11R - S: Remaining right seminal vesicle.

[page 5 of 5]
Gender: Male	Birth Date:	Admit Protocol:
Admit Protocol:	Admit Protocol:	Age:
		Location:

Surgical Pathology**Final Results**

11T - Y: Left Seminal vesicle and vas deferens where they remain attached.

11ZZ - CC: Remaining left vas deferens.

11DD - EE: Remaining left seminal vesicle.

Gross description dictated t on Additional gross
description dictated by on

No consultants

Accessioned:

Final Report Signed Out:

<Resident Signature>

<Sign Out Dr. Signature>

Date Report Signed:

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974.

Requested By:

Do not file in Medical Record

Source: NCI Genomic Data Commons file 3c9e4f33-f7ed-4c8f-9cc1-5411da435a28 (TCGA-VN-A88K.C990DBAF-40D6-4D19-8345-62495C3959A0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).